Somatic mutation profile of tumor specimen TCGA-FK-A3SH-01A (aliquot TCGA-FK-A3SH-01A-11D-A22D-08) from TCGA case TCGA-FK-A3SH, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 50.9 years (18,609 days).
Specimen TCGA-FK-A3SH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a28a0a0-8e1a-4c25-83a0-90344b1a3fa4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FK-A3SH-10A (Blood Derived Normal), aliquot TCGA-FK-A3SH-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f5703c0-b16a-4d5b-a7fb-11e20aa9414e

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C2CD3 | c.5459C>T p.A1820V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs780778726, COSV58091136; called by muse, mutect2, varscan2
- DNTTIP1 | c.10A>T p.T4S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as rs753122969, COSV54784665; called by muse, mutect2, varscan2
- HOXD12 | c.657C>A p.N219K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV66832401, COSV66832622; called by muse, mutect2, varscan2
- NHSL2 | c.2008A>C p.I670L (on ENST00000510661; = p.I1036L on NM_001013627.2) | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65452723, COSV65453419; called by muse, mutect2
- SLCO2B1 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56933807, COSV99214855; called by muse, mutect2
- STAT2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV58474703; called by muse, mutect2
- ZMIZ1 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1444943859, COSV57891783; called by muse, mutect2
- BTK | c.6C>T p.A2= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as rs372818780, COSV58117209, COSV58118150; called by muse, mutect2
- CFH | c.3369C>T p.F1123= | Silent (SNP) | VAF 14/222 reads (6%) | catalogued as COSV66406065; called by muse, mutect2
- RET | c.1440A>G p.E480= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV60689421; called by muse, mutect2, varscan2
- SERPINE3 | c.48C>T p.L16= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV68545021; called by muse, mutect2, varscan2
- USP2 | c.90C>T p.Y30= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV52728130; called by muse, mutect2
